Surgical pathology report (de-identified scan), TCGA case TCGA-LP-A4AW, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site ILSBIO, specimen TCGA-LP-A4AW-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3

Carcinoma, squamous cell,
Keratinizing, NOS 8071/3

Site: cervix, NOS C53.9

W 9/26/12

Clinical Case Report

(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	158 cm	☐ Single ☒ Married	White	36.7
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☐ Male ☒ Female	52 kg		110/70	69

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Abnormal vaginal bleeding
Symptoms:	Vaginal bleeding.
Clinical Findings:	- Vaginal: normal. - ulcer in the cervix
Performance Scale (Karnofsky Score):	
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
NO				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
Normal			

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☒ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:		Hormone Replacement Therapy: NO

SOCIAL HISTORY				
Occupation: farmer		Environmental Hazards: NO		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
NO		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: NO		CEA	☐ Negative ☐ Positive: NO		
Hep B	☒ Negative ☐ Positive: NO		CA 15-3	☐ Negative ☐ Positive: NO		
Hep C	☐ Negative ☐ Positive: NO		CA 19-9	☐ Negative ☐ Positive: NO		
AFP	☐ Negative ☐ Positive: NO		PSA	☐ Negative ☐ Positive: NO		
Other:	☐ Negative ☐ Positive: NO		Other:	☐ Negative ☐ Positive: NO		
B/T Cell Markers: NO						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Normal	
X-Ray	Normal	
CT	no	
Endoscopy	no	
MRI	no	
Biopsy	Pap Smear: adenocarcinoma.	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Cervical cancer		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T	N	M
Stage: Ia.		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Radical hysterectomy pelvic lymph node		
Primary Tumor		
Organ	Detailed Location	Size
Cervix	Limited to endocervix	4 x 3 x 2.5 cm
Extension of Tumor		
Limited to cervix		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	Pelvic	3.
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
No		
Surgical Staging		
T	N	M
Stage: Ia		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
no.				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _

_____ Date:

Preserved by: _

_____ Date:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4		4		2		4	
Time to LN2		Time to Formalin		Time to LN2			
10 min		150 min		07 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
cervix	4 x 3 x 2.5 cm	exocervix - endocervix	0 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
pelvic	3	no	
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Pathological Staging			
pT	N	M	Stage: 1b (FIGO)
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration	☒		Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	☒		Glandular cell			Round Cell			Large Cell		
Spindle Cell	☒		Cell Stratification			Fibroblast			Small Cell		
Keratin	☒		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	☒		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl	☒		Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: D1 50%, D2 60%, D3 60%, D4 60%											

2. Cellular Differentiation:

Well	Moderately	Poor
☒		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism		☒		
Nucleolar Prominent		☒		
Multinucleated Giant Cell		☒		
Mitotic Activity		☒		
Nuclear Grade		☒		

Histological Diagnosis: Keratinizing Squamous Cell Carcinoma

Comments: _____

6-1

Director, Research Pathology

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Reviewed/Revised	8/20/12	

Source: NCI Genomic Data Commons file 67bb0211-8981-4683-9978-1894041dd4fc (TCGA-LP-A4AW.6FE2BF04-559B-4650-921B-C1674E76EEEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).